Somatic mutation profile of tumor specimen TCGA-66-2742-01A (aliquot TCGA-66-2742-01A-01D-0983-08) from TCGA case TCGA-66-2742, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.3 years (25,688 days).
Specimen TCGA-66-2742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 897a9b06-b2e6-4ff8-a833-98e7fc10773c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2742-11A (Solid Tissue Normal), aliquot TCGA-66-2742-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/019ed7d7-2b99-4b7f-adcf-2c638da2be8e

The open-access MAF lists 241 somatic variants for this specimen: 181 protein-altering or splice-affecting, 54 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 54, Nonsense Mutation 15, Frame Shift Del 8, Splice Site 3, Intron 3, Splice Region 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 53/186 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as rs1567541975, COSV52696505; ClinVar: pathogenic; called by muse, varscan2
- ABCA4 | c.5836-2A>G p.X1946_splice | Splice Site (SNP) | VAF 10/38 reads (26%) | catalogued as CD014443, CS117281, CS161784, COSV64673393; called by muse, mutect2, varscan2
- ACKR1 | c.719G>A p.G240D | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.986); catalogued as COSV63672730; called by muse, mutect2, varscan2
- ADAM11 | c.382-1G>A p.X128_splice | Splice Site (SNP) | VAF 30/98 reads (31%) | catalogued as COSV52346174; called by muse, varscan2
- ADAMTS20 | c.1508T>C p.I503T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs541906590, COSV67131120; called by muse, mutect2, varscan2
- ADGRV1 | c.11266A>G p.I3756V | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs369990572; called by muse, mutect2, varscan2
- ALK | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as rs1558446131, COSV66567348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP002512.3 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54406544; called by muse, mutect2, varscan2
- APBB1IP | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63302482; called by muse, mutect2, varscan2
- APOB | c.8057G>A p.W2686* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV51934567, COSV99268469; called by muse, mutect2, varscan2
- ASB6 | c.762C>G p.S254R | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52964968; called by muse, mutect2, varscan2
- ASTE1 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV53908589, COSV99393613; called by muse, mutect2, varscan2
- ATG4C | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100508538; called by muse, mutect2, varscan2
- ATP13A5 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100665034, COSV60869021; called by muse, mutect2, varscan2
- BCL2A1 | c.481A>T p.T161S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV51213143; called by muse, mutect2, varscan2
- BOD1L1 | c.647G>T p.S216I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs756264538, COSV99240251; called by muse, mutect2, varscan2
- C7orf33 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as COSV61023094; called by muse, varscan2
- CAPN15 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760208625, COSV54835811; called by muse, mutect2, varscan2
- CAPN9 | c.1065G>T p.Q355H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV55233365; called by muse, mutect2, varscan2
- CAPN9 | c.1066G>T p.G356* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV55233384; called by muse, mutect2, varscan2
- CATSPERD | c.1968C>A p.N656K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs1341220787, COSV58465264; called by muse, mutect2, varscan2
- CCDC102B | c.606G>A p.K202= | Splice Region (SNP) | VAF 12/103 reads (12%) | catalogued as rs1317571098, COSV60141120; called by muse, mutect2, varscan2
- CCDC18 | c.3878C>A p.T1293N (on ENST00000343253 / NM_001306076.1; = p.T1294N on NM_206886.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV58143271; called by muse, mutect2, varscan2
- CCDC85A | c.1007C>A p.P336Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV101339549, COSV68152566; called by muse, mutect2, varscan2
- CD101 | c.2842A>G p.R948G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56717909; called by mutect2, varscan2
- CD3D | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52674797; called by muse, mutect2, varscan2
- CD5L | c.56C>A p.A19E | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63821922; called by muse, mutect2, varscan2
- CD8A | c.145A>G p.N49D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV52157396; called by muse, mutect2, varscan2
- CDH18 | c.1860_1862del p.L621del | In Frame Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs774418996; called by pindel, varscan2
- CHRM5 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV67247321; called by muse, mutect2, varscan2
- CLEC3A | c.494G>A p.R165H (on ENST00000651443; = p.R156H on NM_005752.6) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1340053356, COSV55221377; called by muse, mutect2, varscan2
- CNTNAP5 | c.1790A>C p.Q597P | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as COSV70471880, COSV70484955; called by muse, mutect2, varscan2
- COL17A1 | c.1741A>T p.K581* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV62226610; called by muse, mutect2, varscan2
- COL22A1 | c.4324C>G p.P1442A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as COSV57335829, COSV57347484; called by muse, mutect2, varscan2
- COL5A3 | c.5128A>T p.S1710C | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV53410320; called by muse, mutect2, varscan2
- CPZ | c.1340C>A p.A447E (on ENST00000360986 / NM_001014447.3; = p.A436E on NM_003652.3) | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200017497, COSV59922922; called by muse, mutect2, varscan2
- CSMD3 | c.2413C>T p.H805Y (on ENST00000297405 / NM_001363185.1; = p.H701Y on NM_052900.3) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV52137642, COSV52234901; called by muse, mutect2, varscan2
- DAB2 | c.995G>T p.S332I | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57914230; called by muse, mutect2, varscan2
- DDX60L | c.3946G>A p.D1316N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52713200; called by muse, mutect2, varscan2
- DELE1 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52004785; called by muse, mutect2, varscan2
- DLC1 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1430286963, COSV52302736; called by muse, mutect2, varscan2
- DOCK4 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV70319876; called by muse, mutect2, varscan2
- DSE | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.723); catalogued as rs1304378291, COSV59063769; called by muse, mutect2, varscan2
- DYRK2 | c.647A>T p.D216V (on ENST00000344096 / NM_006482.3; = p.D143V on NM_003583.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59846054; called by muse, mutect2, varscan2
- EDNRB | c.421A>G p.K141E (on ENST00000377211 / NM_001201397.1; = p.K51E on NM_000115.5) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57522150; called by muse, mutect2, varscan2
- EPB41L3 | c.2645C>A p.A882E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59452661; called by muse, mutect2, varscan2
- ERBB3 | c.3358A>G p.R1120G | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV57252851; called by muse, mutect2, varscan2
- ERO1B | c.856C>A p.R286S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51595709, COSV51595996; called by muse, mutect2, varscan2
- EXOG | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371616022, COSV55063243; called by muse, mutect2, varscan2
- FAM47C | c.1424G>A p.C475Y | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.236); catalogued as COSV63723820; called by muse, mutect2, varscan2
- FAM53B | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV61560479; called by muse, varscan2
- FAM83C | c.1070T>A p.M357K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs771175139, COSV65582964; called by muse, mutect2, varscan2
- FBN2 | c.4793G>A p.G1598E | Missense Mutation (SNP) | VAF 112/276 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52511343, COSV52528328; called by muse, mutect2, varscan2
- FGD2 | c.818C>G p.A273G | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV51463588; called by muse, mutect2, varscan2
- FN1 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV60546362, COSV60552265; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.956A>G p.H319R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); catalogued as rs200580098, COSV58553525; called by muse, mutect2, varscan2
- GALNT2 | c.1354C>G p.Q452E | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV64192904, COSV64194660; called by muse, mutect2, varscan2
- GAREM1 | c.1919G>T p.S640I (on ENST00000269209 / NM_001242409.2; = p.S639I on NM_022751.3) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV52509142; called by muse, varscan2
- GGH | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376001011; called by muse, mutect2, varscan2
- GP2 | c.511T>C p.W171R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56893903; called by muse, mutect2, varscan2
- GPC5 | c.649A>T p.R217W | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65596965; called by muse, mutect2, varscan2
- GPR12 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771882043, COSV67344317; called by mutect2, varscan2
- HDAC9 | c.2814G>T p.K938N | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.181); catalogued as COSV67772732; called by muse, mutect2, varscan2
- HDC | c.1575G>C p.Q525H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV51070018; called by muse, mutect2, varscan2
- HK2 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV51875245; called by muse, mutect2, varscan2
- HSCB | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53262377; called by muse, mutect2, varscan2
- HTR3C | c.535_536insG p.T179Sfs*57 | Frame Shift Ins (INS) | VAF 61/325 reads (19%) | catalogued as COSV100570743; called by mutect2, pindel, varscan2
- HTR3E | c.770C>A p.P257H (on ENST00000415389 / NM_001256613.1; = p.P272H on NM_182589.2) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58946786; called by muse, varscan2
- IKBIP | c.454C>G p.Q152E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV61081677; called by muse, mutect2
- JAG2 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs202068896, COSV59308802; called by mutect2, varscan2
- KCNH1 | c.1999T>C p.C667R (on ENST00000271751 / NM_172362.3; = p.C640R on NM_002238.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55080586; called by muse, mutect2, varscan2
- KCNH5 | c.1917C>A p.H639Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV59759515; called by muse, mutect2, varscan2
- KDM6A | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 22/33 reads (67%) | catalogued as COSV65038777, COSV65040016, COSV65045978; called by muse, mutect2, varscan2
- KIAA0319 | c.689C>A p.P230H | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV65498202; called by muse, mutect2, varscan2
- KLHL32 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65111919; called by muse, mutect2, varscan2
- KMT2B | c.2186A>G p.N729S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV52890452; called by muse, mutect2, varscan2
- LAPTM5 | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53853215; called by muse, mutect2, varscan2
- LARGE1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.147); catalogued as rs763697782, COSV61661514; ClinVar: uncertain significance; called by mutect2, varscan2
- LDHD | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as rs780165015, COSV55580815; called by muse, mutect2, varscan2
- LIPG | c.978G>T p.M326I | Missense Mutation (SNP) | VAF 55/150 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs779692319, COSV54296094; called by muse, mutect2, varscan2
- LRRC31 | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.905); catalogued as COSV52980812; called by muse, mutect2, varscan2
- LRRTM1 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54440880; called by muse, mutect2, varscan2
- LY75 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55105305; called by muse, mutect2, varscan2
- LYST | c.10491G>T p.Q3497H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV67706768; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs374099237; called by muse, mutect2, varscan2
- MAZ | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV50714946; called by muse, mutect2, varscan2
- MBNL1 | c.1090G>T p.A364S (on ENST00000282486 / NM_207293.2; = p.A358S on NM_021038.5 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs533774724, COSV56827952; called by muse, mutect2, varscan2
- MCF2 | c.1397T>A p.L466* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV58484363; called by muse, mutect2
- MEFV | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV54821563; called by muse, mutect2, varscan2
- MGAT4C | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.69); catalogued as rs748796788, COSV59829726; called by mutect2, varscan2
- MON1A | c.1652G>A p.S551N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56560407; called by muse, mutect2, varscan2
- MPO | c.1019G>C p.S340T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1314583848, COSV56563640; called by muse, mutect2
- MRGPRX1 | c.346G>C p.V116L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs145122494, COSV100246168; called by muse, mutect2, varscan2
- MUC16 | c.34782C>A p.N11594K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67452194, COSV67464043; called by muse, mutect2, varscan2
- MUC16 | c.11497G>C p.A3833P | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV67464048; called by muse, mutect2
- MUC16 | c.7132A>G p.I2378V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1273384254, COSV67464053; called by muse, mutect2, varscan2
- MYBPC1 | c.2791C>A p.R931S (on ENST00000550270 / NM_206820.2; = p.R938S on NM_002465.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs372724805, COSV100638245; called by muse, mutect2, varscan2
- MYH2 | c.1380C>G p.I460M | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55433398, COSV55437678; called by muse, mutect2, varscan2
- MYH4 | c.4436G>A p.R1479H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as rs1488567340, COSV55117754; called by muse, mutect2, varscan2
- NCAN | c.3156C>A p.C1052* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as COSV53050724; called by muse, mutect2, varscan2
- NLRP7 | c.2691G>T p.E897D (on ENST00000340844 / NM_206828.3; = p.E869D on NM_139176.3) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1030968324, COSV60174164; called by muse, mutect2, varscan2
- NPC1 | c.3378C>G p.I1126M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.744); catalogued as rs777004814, COSV52571823; called by muse, mutect2, varscan2
- NR1H4 | c.93T>A p.S31R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV51851638; called by muse, mutect2, varscan2
- NSUN6 | c.1225A>T p.R409W | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as COSV56622682; called by muse, mutect2, varscan2
- NUFIP1 | c.1322A>T p.Y441F | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV64791166; called by muse, mutect2, varscan2
- NUP205 | c.1473+1G>A p.X491_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | catalogued as COSV53668487; called by muse, mutect2, varscan2
- NXF1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 115/183 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.515); catalogued as COSV53673985; called by muse, mutect2, varscan2
- OPN1SW | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs749665821, COSV50821287; called by muse, mutect2, varscan2
- OR10K1 | c.192del p.I65Sfs*80 | Frame Shift Del (DEL) | VAF 80/206 reads (39%) | catalogued as COSV56871842; called by mutect2, pindel, varscan2
- OR10T2 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1410440565, COSV57781165, COSV57782057; called by muse, mutect2, varscan2
- OR2T33 | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as COSV58815293; called by muse, mutect2, varscan2
- OR51V1 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV58315060; called by muse, mutect2, varscan2
- OR5AC2 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.877); catalogued as COSV62279439; called by muse, mutect2, varscan2
- OR8B2 | c.813A>C p.K271N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66664629, COSV66664848; called by muse, mutect2, varscan2
- OR8B2 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as COSV66664591, COSV66664632; called by muse, mutect2, varscan2
- PCDHA6 | c.2285A>T p.E762V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV65343934; called by muse, mutect2, varscan2
- PCDHGA4 | c.1932G>T p.E644D | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV53943607; called by muse, mutect2, varscan2
- PDILT | c.1552G>C p.A518P | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56700987, COSV56701781; called by muse, mutect2
- PHLDB2 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV101208778, COSV67310972; called by muse, mutect2, varscan2
- PI15 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52641189, COSV99477782; called by mutect2, varscan2
- PIGQ | c.25A>T p.T9S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.027); catalogued as COSV99216488; called by mutect2, varscan2
- PKHD1 | c.8851G>A p.G2951R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61874316; called by muse, varscan2
- PKHD1L1 | c.7825G>T p.G2609C | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763078437, COSV65742614; called by muse, mutect2, varscan2
- PLEKHA8 | c.1285A>T p.I429F | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); catalogued as COSV51650950; called by muse, mutect2, varscan2
- PRLR | c.1453G>T p.E485* | Nonsense Mutation (SNP) | VAF 29/89 reads (33%) | catalogued as COSV51495371; called by muse, mutect2, varscan2
- PRPF38B | c.1501A>T p.S501C | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV64223838; called by muse, mutect2, varscan2
- PSD | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.535); catalogued as rs754453263, COSV50041880; called by muse, mutect2, varscan2
- PXDN | c.2968C>A p.L990M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53233298, COSV53241626; called by muse, mutect2
- RALGAPB | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as rs768437434, COSV53436332; called by muse, mutect2, varscan2
- RASGRF1 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150222693; called by muse, mutect2, varscan2
- REXO5 | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV54471941; called by muse, mutect2, varscan2
- RP1L1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs762473280, COSV66754699; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTP2 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 22/49 reads (45%) | catalogued as COSV64078988; called by muse, mutect2, varscan2
- SELP | c.785G>A p.C262Y | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55251633; called by muse, mutect2, varscan2
- SEMA6D | c.3068C>G p.P1023R (on ENST00000316364 / NM_153618.2; = p.P961R on NM_020858.2) | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV60376829; called by muse, mutect2, varscan2
- SEZ6 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139179377, COSV57982123; called by muse, mutect2, varscan2
- SLC10A2 | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV104392857, COSV55358765; called by muse, mutect2, varscan2
- SLC12A6 | c.409G>C p.E137Q (on ENST00000354181 / NM_001365088.1; = p.E86Q on NM_005135.2) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV51625852, COSV51630989; called by muse, mutect2, varscan2
- SLC13A1 | c.1756G>C p.A586P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52010943; called by muse, varscan2
- SLC1A6 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV55670130, COSV99694311; called by muse, mutect2, varscan2
- SLC20A2 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as CD1410694, COSV60602681; called by muse, mutect2, varscan2
- SLC6A3 | c.927T>C p.S309= | Splice Region (SNP) | VAF 35/164 reads (21%) | catalogued as COSV54364075; called by muse, mutect2, varscan2
- SNW1 | c.1228A>G p.R410G | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53174123; called by muse, varscan2
- SNW1 | c.1178C>A p.A393D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53174132; called by muse, varscan2
- SPATS2L | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV62348046; called by muse, mutect2, varscan2
- STAB2 | c.5722A>G p.T1908A | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV66338676; called by muse, varscan2
- STK31 | c.860G>A p.G287D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.058); catalogued as COSV63455875; called by muse, mutect2, varscan2
- STMN2 | c.174G>C p.L58F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55219355; called by muse, mutect2, varscan2
- SUCO | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as COSV55265006; called by muse, mutect2, varscan2
- SVIL | c.2928C>A p.Y976* (on ENST00000355867 / NM_021738.3; = p.Y550* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as COSV63443234; called by muse, mutect2, varscan2
- TP53 | c.1044G>T p.L348F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52730754, COSV52829880; called by muse, varscan2
- TPM3 | c.532G>T p.E178* | Nonsense Mutation (SNP) | VAF 42/185 reads (23%) | catalogued as COSV55136006; called by muse, mutect2, varscan2
- TRIM37 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51883654; called by muse, mutect2, varscan2
- TTF2 | c.2309A>G p.Q770R | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399982848, COSV65632572; called by muse, mutect2, varscan2
- TTN | c.18588G>T p.Q6196H (on ENST00000591111; = p.Q5269H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | PolyPhen benign (0); catalogued as COSV60041352; called by muse, mutect2, varscan2
- TYRO3 | c.778G>C p.V260L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.07); catalogued as COSV55483137; called by muse, mutect2
- VASP | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV55606657; called by muse, mutect2, varscan2
- ZFAT | c.3161G>T p.W1054L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64738157; called by muse, mutect2, varscan2
- ZFP64 | c.1187A>T p.D396V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs749137139, COSV53798885; called by muse, mutect2, varscan2
- ZIC4 | c.734T>G p.F245C | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67171698; called by muse, mutect2, varscan2
- ZNF106 | c.4888G>T p.A1630S | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55516509; called by muse, mutect2, varscan2
- ZNF229 | c.379C>A p.Q127K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.439); catalogued as COSV52161715; called by muse, mutect2, varscan2
- ZNF260 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1456033259, COSV72951207; called by muse, mutect2, varscan2
- ZNF37A | c.1568A>G p.Y523C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756370390, COSV61073576; called by mutect2, varscan2
- ZNF407 | c.3052A>T p.K1018* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as COSV55252315; called by muse, mutect2, varscan2
- ZNF638 | c.5036G>A p.R1679H | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs1256448486, COSV52486840, COSV52490816; called by muse, mutect2, varscan2
- ZNF76 | c.1013T>C p.V338A | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as rs766364824, COSV57591439; called by muse, mutect2, varscan2
- ZSCAN20 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV63682573; called by muse, mutect2, varscan2
- ARID4A | c.1620del p.D541Tfs*34 | Frame Shift Del (DEL) | VAF 42/228 reads (18%) | called by mutect2, varscan2
- CARD8 | c.341del p.D114Afs*27 (on ENST00000651546 / NM_001184900.3; = p.D64Afs*27 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- CASP4 | c.360_361del p.R121Sfs*2 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel
- IGKV3-7 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MRC1 | c.1675C>A p.P559T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.443); called by muse, mutect2
- MRC1 | c.1676C>A p.P559H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- PDE3A | c.3038del p.C1013Sfs*9 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- PHKG1 | c.621_627del p.Y207* | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- RBP3 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRGC2 | c.226A>C p.T76P | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TSSK2 | c.868del p.E290Rfs*16 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- ULK2 | c.686del p.N229Tfs*4 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ABCC11 | c.3549C>T p.S1183= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV62322931; called by muse, mutect2, varscan2
- ADAMTS5 | c.2793G>A p.*931= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53178881; called by muse, mutect2, varscan2
- ALPK2 | c.1878C>T p.G626= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV64492887; called by muse, mutect2, varscan2
- ANK2 | c.867C>A p.G289= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs113692517, COSV52160080; called by muse, mutect2, varscan2
- ANKRD30A | c.855A>G p.A285= (on ENST00000611781; = p.A229= on NM_052997.2) | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV64609706; called by muse, mutect2, varscan2
- ASPM | c.10218A>T p.T3406= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV54129495; called by muse, mutect2, varscan2
- BPIFA3 | c.670T>C p.L224= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV64925831; called by muse, mutect2, varscan2
- BRS3 | c.147C>A p.A49= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV65710989; called by muse, mutect2, varscan2
- C10orf62 | c.615C>T p.H205= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV65705214; called by muse, mutect2, varscan2
- CCDC14 | c.1746G>T p.G582= (on ENST00000488653; = p.G534= on NM_022757.5) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV59944605; called by muse, mutect2, varscan2
- CDC40 | c.1125A>T p.V375= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV57009432; called by muse, mutect2, varscan2
- CFLAR | c.582C>T p.L194= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV57936980; called by muse, mutect2
- CLN8 | c.549C>G p.G183= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV58670401; called by muse, mutect2, varscan2
- CNTNAP2 | c.1965A>T p.P655= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as COSV62177645; called by muse, mutect2, varscan2
- CR2 | c.465A>T p.P155= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV65507536; called by muse, mutect2, varscan2
- CREBBP | c.2331T>C p.G777= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs1230610112, COSV52123032; called by muse, mutect2, varscan2
- CTU2 | c.1248G>A p.Q416= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV56336994; called by muse, mutect2, varscan2
- DCAF12L1 | c.480C>T p.S160= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV64421748; called by muse, mutect2, varscan2
- DLC1 | c.522G>T p.L174= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV52302771; called by mutect2, varscan2
- EVI5 | c.978T>G p.T326= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as COSV64827012; called by muse, mutect2, varscan2
- FAT3 | c.3759G>A p.Q1253= | Silent (SNP) | VAF 118/222 reads (53%) | catalogued as COSV53107270, COSV53138707; called by muse, mutect2, varscan2
- IGSF8 | c.1395T>A p.S465= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV58758001; called by muse, mutect2, varscan2
- KLHL41 | c.327G>A p.L109= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV52930108; called by muse, mutect2, varscan2
- LAMA2 | c.4188G>T p.P1396= | Silent (SNP) | VAF 30/56 reads (54%) | catalogued as COSV70344786, COSV70346493; called by muse, varscan2
- LILRB1 | c.1119C>A p.A373= (on ENST00000427581; = p.A337= on NM_006669.6) | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV61117815; called by muse, varscan2
- LMAN1L | c.408C>A p.I136= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV59001889, COSV59001952; called by muse, mutect2, varscan2
- MAGEA8 | c.99T>C p.A33= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV54064100; called by muse, mutect2
- MAP3K19 | c.1578T>C p.N526= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV59638709; called by muse, mutect2, varscan2
- MPV17 | c.87G>T p.L29= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV51990305; called by muse, mutect2, varscan2
- MYOD1 | c.162C>A p.G54= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV51452699, COSV51453618; called by muse, mutect2, varscan2
- NAA25 | c.2019A>G p.E673= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV55704147; called by muse, mutect2, varscan2
- NRXN3 | c.2772C>A p.V924= (on ENST00000335750 / NM_001330195.2; = p.V551= on NM_004796.6) | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV59745450, COSV59785978; called by muse, mutect2, varscan2
- NUMBL | c.453C>T p.R151= | Silent (SNP) | VAF 45/149 reads (30%) | catalogued as COSV53285317; called by muse, mutect2, varscan2
- OR4C11 | c.129T>A p.I43= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV56353107; called by muse, mutect2, varscan2
- OR4K5 | c.111C>A p.V37= | Silent (SNP) | VAF 10/104 reads (10%) | catalogued as COSV60003429; called by mutect2, varscan2
- OR51B6 | c.615C>G p.V205= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs766271397, COSV66512970, COSV66513007; called by muse, mutect2, varscan2
- OR6B1 | c.390C>A p.L130= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs1284598465, COSV68770102; called by muse, mutect2, varscan2
- PARN | c.1536T>C p.Y512= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV58365849; called by muse, mutect2, varscan2
- PDLIM1 | c.642G>A p.T214= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs762617070, COSV61473925; called by muse, mutect2, varscan2
- PIKFYVE | c.2928G>T p.P976= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as COSV100011347; called by muse, mutect2, varscan2
- PSMD10 | c.24A>T p.L8= | Silent (SNP) | VAF 51/80 reads (64%) | catalogued as COSV54264091; called by muse, mutect2, varscan2
- RGL3 | c.420C>T p.N140= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV62697838; called by muse, mutect2, varscan2
- SH2D4B | c.855G>A p.P285= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs770764104, COSV57895229; called by muse, varscan2
- SLC32A1 | c.264C>A p.G88= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV54146640; called by muse, mutect2, varscan2
- SLCO2B1 | c.849T>A p.A283= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV56934996; called by muse, mutect2, varscan2
- SNW1 | c.1179T>C p.A393= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs759563866, COSV53174128; called by muse, varscan2
- TEKT4 | c.1152A>G p.L384= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV54624731; called by muse, mutect2, varscan2
- TENM3 | c.1101T>C p.S367= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV69307260; called by muse, mutect2, varscan2
- TMPPE | c.1263A>G p.T421= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV56563475; called by muse, mutect2, varscan2
- TOX | c.1053G>C p.L351= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV63266292; called by muse, mutect2, varscan2
- TSPAN7 | c.717G>T p.R239= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs1287528855, COSV54530582; called by muse, mutect2, varscan2
- USP36 | c.3219C>T p.D1073= | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as rs148007252; called by muse, mutect2, varscan2
- VPS13D | c.1050A>G p.V350= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs1277226144, COSV62529058; called by muse, mutect2, varscan2
- ZNF26 | c.1029A>G p.Q343= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1406248710; called by muse, mutect2, varscan2
- ADGRE4P | n.131C>A | RNA (SNP) | VAF 11/79 reads (14%) | catalogued as rs766933976; called by muse, mutect2, varscan2
- OBSCN | c.18662-2232C>T | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99483660; called by muse, mutect2, varscan2
- OR3A4P | n.611C>T | RNA (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-44377G>T | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as COSV67443566; called by muse, mutect2, varscan2
- SYTL2 | c.1459+3314C>T | Intron (SNP) | VAF 15/63 reads (24%) | catalogued as rs146138820; called by muse, mutect2, varscan2
- TCEAL5 | c.-1C>T | 5'UTR (SNP) | VAF 26/42 reads (62%) | catalogued as COSV101013182; called by muse, mutect2, varscan2
